Somatic mutation profile of tumor specimen TCGA-36-2539-01A (aliquot TCGA-36-2539-01A-01D-1526-09) from TCGA case TCGA-36-2539, project TCGA-OV (Ovarian Serous Cystadenocarcinoma).
Specimen TCGA-36-2539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1230eeb-f612-4b31-a505-8e6b3d60bdf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2539-10A (Blood Derived Normal), aliquot TCGA-36-2539-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00ff96c0-74fd-4059-ad77-22373d5eb44f

The open-access MAF lists 86 somatic variants for this specimen: 67 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 53, Silent 19, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.859G>C p.E287Q (on ENST00000281708 / NM_001349798.2; = p.E207Q on NM_018315.5) | Missense Mutation (SNP) | VAF 62/164 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55921895, COSV99662126; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 125/331 reads (38%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs866189730, COSV52825642; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.5012C>G p.P1671R | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99784105; called by muse, mutect2
- ARHGAP32 | c.5695C>T p.Q1899* (on ENST00000310343 / NM_001378025.1; = p.Q1550* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 54/284 reads (19%) | catalogued as rs754498145; called by muse, mutect2, varscan2
- BATF3 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs925093445, COSV99695930; called by muse, mutect2, varscan2
- BICRAL | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV58403779; called by muse, mutect2, varscan2
- CASR | c.1020G>C p.R340S | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56135936, COSV56136915; called by muse, mutect2, varscan2
- CLCF1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs1199106923; called by muse, mutect2
- CPT1C | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs765359581, COSV54922336; called by muse, mutect2, varscan2
- DOCK2 | c.4357G>A p.V1453I | Missense Mutation (SNP) | VAF 58/837 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs749664205, COSV56973731; called by muse, mutect2
- ERBB4 | c.3460A>G p.M1154V | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs778431214; called by muse, mutect2, varscan2
- FHIT | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs769130211, COSV59286231, COSV59319274; called by muse, mutect2
- FRMPD1 | c.1782C>A p.N594K | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs756472976; called by muse, mutect2
- JHY | c.108T>G p.H36Q | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV56221279; called by muse, mutect2, varscan2
- KHDC4 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64165908; called by muse, mutect2, varscan2
- MESD | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 109/304 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as rs770014867; called by muse, mutect2, varscan2
- MPO | c.286A>C p.M96L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs906727603; called by muse, mutect2, varscan2
- MTIF2 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as rs989478739; called by muse, mutect2
- NF2 | c.1738-1G>C p.X580_splice | Splice Site (SNP) | VAF 44/228 reads (19%) | catalogued as CS961646; called by muse, varscan2
- NLGN4X | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs775611375, COSV52005569; called by muse, mutect2
- PCDHB14 | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554289316; called by muse, mutect2
- PHC1 | c.1808A>G p.H603R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as rs1565521592; called by muse, mutect2, varscan2
- SLITRK2 | c.181dup p.Q61Pfs*35 | Frame Shift Ins (INS) | VAF 109/264 reads (41%) | catalogued as rs781792891; called by mutect2, varscan2
- UBE2O | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60061562, COSV60062487; called by muse, mutect2, varscan2
- ABCG8 | c.881T>C p.L294S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADNP | c.883G>C p.V295L | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- BDKRB2 | c.796A>G p.R266G | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2
- CATSPER1 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 111/374 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC40 | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPLANE1 | c.7813-1G>T p.X2605_splice | Splice Site (SNP) | VAF 62/147 reads (42%) | called by muse, mutect2, varscan2
- CRACR2A | c.657G>T p.E219D | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CRAT | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRYZL1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 58/281 reads (21%) | called by muse, mutect2, varscan2
- CTHRC1 | c.119C>G p.A40G | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.042); called by muse, mutect2
- CTLA4 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 112/518 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- DHRS7B | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 11/337 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- DNAAF6 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAH5 | c.8601T>G p.I2867M | Missense Mutation (SNP) | VAF 105/260 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DYDC2 | c.507G>T p.M169I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- FAT2 | c.12110C>A p.P4037H | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FCGBP | c.12020G>T p.C4007F | Missense Mutation (SNP) | VAF 96/267 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GALT | c.544A>G p.N182D | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GCDH | c.1119del p.N373Kfs*28 | Frame Shift Del (DEL) | VAF 35/159 reads (22%) | called by mutect2, pindel, varscan2
- GGCX | c.2061_2078del p.K688_R693del | In Frame Del (DEL) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- GRM7 | c.2002A>T p.I668F | Missense Mutation (SNP) | VAF 12/434 reads (3%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2
- GTF3C3 | c.843G>T p.L281F | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LYRM4 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MACF1 | c.6621G>T p.Q2207H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- MDFI | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 65/390 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- MRE11 | c.1270G>C p.G424R | Missense Mutation (SNP) | VAF 33/439 reads (8%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.717); called by muse, mutect2
- NKAIN2 | c.47T>C p.M16T | Missense Mutation (SNP) | VAF 24/485 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- PABPC4 | c.150_174del p.L52Sfs*13 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- PANX3 | c.433A>T p.S145C | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PDP1 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG3 | c.1105G>T p.E369* (on ENST00000394691; = p.E425* on NM_001308147.2) | Nonsense Mutation (SNP) | VAF 45/194 reads (23%) | called by muse, mutect2, varscan2
- PSEN2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SERPINH1 | c.459C>A p.H153Q | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SIPA1L1 | c.5405A>T p.D1802V | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC14A2 | c.1471A>T p.K491* | Nonsense Mutation (SNP) | VAF 113/439 reads (26%) | called by muse, mutect2, varscan2
- SLC37A1 | c.1136-1G>A p.X379_splice | Splice Site (SNP) | VAF 55/258 reads (21%) | called by muse, mutect2, varscan2
- SOCS7 | c.1889A>T p.E630V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- THTPA | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 113/486 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIAM1 | c.4708A>T p.S1570C | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- UBA6 | c.2060dup p.L688Vfs*3 | Frame Shift Ins (INS) | VAF 22/151 reads (15%) | called by mutect2, pindel, varscan2
- VWC2 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.52); called by muse, mutect2
- ZPR1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 138/555 reads (25%) | called by muse, mutect2, varscan2
- ABCD4 | c.465G>A p.R155= | Silent (SNP) | VAF 16/405 reads (4%) | catalogued as COSV53994480; called by muse, mutect2
- ANKRD44 | c.2658C>T p.G886= | Silent (SNP) | VAF 20/342 reads (6%) | catalogued as rs772261040; called by muse, mutect2
- BCO1 | c.1323C>G p.L441= | Silent (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- CA11 | c.885C>A p.A295= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- CNNM2 | c.1263C>T p.T421= | Silent (SNP) | VAF 61/137 reads (45%) | called by muse, mutect2, varscan2
- DDB1 | c.1341A>G p.E447= | Silent (SNP) | VAF 107/449 reads (24%) | called by muse, mutect2, varscan2
- DDC | c.105C>T p.P35= | Silent (SNP) | VAF 135/504 reads (27%) | catalogued as rs751163340, CD146244, COSV63567136; called by muse, mutect2, varscan2
- DSCAML1 | c.5460C>A p.R1820= (on ENST00000321322; = p.R1760= on NM_020693.4) | Silent (SNP) | VAF 101/394 reads (26%) | called by mutect2, varscan2
- NFE2L3 | c.1656T>C p.D552= | Silent (SNP) | VAF 88/287 reads (31%) | catalogued as rs374986558; called by muse, mutect2, varscan2
- NFIA | c.1032G>A p.T344= | Silent (SNP) | VAF 22/364 reads (6%) | catalogued as rs1202750294; called by muse, mutect2
- OR2B6 | c.324G>T p.G108= | Silent (SNP) | VAF 121/253 reads (48%) | catalogued as rs370729151; called by muse, mutect2, varscan2
- PCDHB1 | c.1656C>G p.V552= | Silent (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- PSD2 | c.849A>T p.S283= | Silent (SNP) | VAF 44/208 reads (21%) | called by muse, mutect2, varscan2
- PTPRS | c.132C>T p.G44= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as rs764980332; called by muse, mutect2, varscan2
- RAPH1 | c.3045G>A p.K1015= | Silent (SNP) | VAF 44/161 reads (27%) | called by muse, mutect2, varscan2
- RBM25 | c.888C>G p.G296= | Silent (SNP) | VAF 73/245 reads (30%) | called by muse, mutect2, varscan2
- RTN4RL2 | c.132G>T p.V44= | Silent (SNP) | VAF 53/221 reads (24%) | called by muse, mutect2, varscan2
- SLC25A43 | c.528G>A p.P176= | Silent (SNP) | VAF 152/457 reads (33%) | catalogued as rs749429476; called by muse, varscan2
- TSPAN17 | c.225G>A p.S75= | Silent (SNP) | VAF 11/355 reads (3%) | catalogued as COSV53781074; called by muse, mutect2
